Somatic mutation profile of tumor specimen C3N-02572-01 (aliquot CPT0147580010) from CPTAC case C3N-02572, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.3 years (18,003 days).
Specimen C3N-02572-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97916723-5fbb-4573-ba15-f771f57df754.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02572-71 (Blood Derived Normal), aliquot CPT0147610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec66addf-db8b-412d-b739-55b50b543f3b

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Intron 3, RNA 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 227/611 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 102/309 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATG14 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.186); catalogued as rs1447380567; called by muse, mutect2
- CELF4 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100611952; called by muse, mutect2, varscan2
- CFAP54 | c.2511G>A p.M837I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1246510043; called by muse, mutect2, varscan2
- CRIM1 | c.2517C>G p.H839Q | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV54869531; called by muse, mutect2
- DSCAML1 | c.4805G>A p.R1602Q (on ENST00000321322; = p.R1542Q on NM_020693.4) | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.357); catalogued as rs143121003; called by muse, mutect2
- FAM47C | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV63725090; called by muse, mutect2
- HMCN1 | c.13973G>C p.S4658T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1558256376; called by muse, mutect2, varscan2
- LRRIQ4 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs747187885, COSV61619280; called by muse, mutect2, varscan2
- PTPRT | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1243407933, COSV61957926; called by muse, mutect2
- SPDYE5 | c.756-1G>A p.X252_splice | Splice Site (SNP) | VAF 64/265 reads (24%) | catalogued as rs782585253; called by muse, mutect2, varscan2
- SSTR2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767248654; called by muse, mutect2
- TRRAP | c.3991G>T p.E1331* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | catalogued as COSV62857305; called by muse, mutect2
- UGT2B4 | c.628del p.R210Gfs*2 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV59316653; called by mutect2, pindel, varscan2
- ABCA3 | c.1189_1191dup p.N397dup | In Frame Ins (INS) | VAF 122/412 reads (30%) | called by pindel, varscan2
- ABCA3 | c.1159_1167del p.I387_Y389del | In Frame Del (DEL) | VAF 76/390 reads (19%) | called by pindel, varscan2
- ABHD17B | c.663dup p.K222* | Frame Shift Ins (INS) | VAF 23/113 reads (20%) | called by mutect2, pindel
- ACY3 | c.366G>C p.M122I | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- CHRM3 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- EBLN1 | c.991A>T p.T331S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ESPNL | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- FBN3 | c.4194C>G p.D1398E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- FNDC1 | c.2794A>T p.T932S | Missense Mutation (SNP) | VAF 36/371 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); called by muse, mutect2
- FSD2 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- GRAP2 | c.968A>C p.N323T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNQ2 | c.2221C>T p.R741C (on ENST00000359125 / NM_172107.4; = p.R713C on NM_004518.6) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LHFPL3 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- MUC16 | c.20015C>A p.T6672K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR12D2 | c.766T>A p.F256I | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.385); called by muse, mutect2
- PCDHGA1 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2
- PMPCB | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.084); called by muse, mutect2
- RNF165 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2
- SECISBP2 | c.2282A>G p.K761R | Missense Mutation (SNP) | VAF 82/659 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPHK1 | c.857A>C p.H286P (on ENST00000392496 / NM_001355139.2; = p.H300P on NM_021972.4) | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SYNE2 | c.4718G>A p.R1573K | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- TIMM29 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- TRIM37 | c.1106T>C p.V369A | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- ACTN4 | c.615C>T p.H205= | Silent (SNP) | VAF 67/556 reads (12%) | called by muse, mutect2, varscan2
- ETV1 | c.936C>T p.F312= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs765227604, COSV54137697; called by muse, mutect2
- NLRP5 | c.3228C>T p.A1076= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- OR5T3 | c.498A>G p.L166= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- PPP1R16B | c.594C>T p.N198= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as rs200868467, COSV55374057; called by muse, mutect2, varscan2
- SHD | c.585G>A p.A195= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs149098681; called by muse, mutect2, varscan2
- SYNE2 | c.4719G>A p.R1573= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- TMPRSS11B | c.393C>T p.I131= | Silent (SNP) | VAF 34/157 reads (22%) | called by muse, varscan2
- UNC13C | c.2721C>T p.H907= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- AC004947.2 | n.101C>A | RNA (SNP) | VAF 25/178 reads (14%) | called by muse, mutect2, varscan2
- FAM90A20P | n.1009G>A | RNA (SNP) | VAF 79/737 reads (11%) | catalogued as rs560227328; called by muse, mutect2, varscan2
- SH3BP5 | c.669+70G>A | Intron (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+8447T>C | Intron (SNP) | VAF 17/368 reads (5%) | called by muse, mutect2
- TUBA1A | c.*20T>G | 3'UTR (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- ZNF334 | c.22-1609del | Intron (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
